Somatic mutation profile of tumor specimen C3N-03184-02 (aliquot CPT0206780009) from CPTAC case C3N-03184, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 35.1 years (12,827 days).
Specimen C3N-03184-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Brain; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 6b068219-8679-48ff-9ab1-36415531d5cd.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-03184-71 (Blood Derived Normal), aliquot CPT0206830002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4569da00-59e1-4037-93c9-2c71beb6a80d

The open-access MAF lists 44 somatic variants for this specimen: 29 protein-altering or splice-affecting, 13 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 26, Silent 13, Nonsense Mutation 1, Splice Region 1, Frame Shift Del 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- RPL5 | c.535C>T p.R179* | Nonsense Mutation (SNP) | VAF 56/150 reads (37%) | catalogued as rs1057520746, CM108640, COSV59874085; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AMOTL2 | c.443G>A p.R148Q | Missense Mutation (SNP) | VAF 225/528 reads (43%) | SIFT deleterious (0.03); PolyPhen benign (0.12); catalogued as rs765364030, COSV51440036; called by muse, mutect2, varscan2
- BRWD3 | c.5237G>A p.R1746Q | Missense Mutation (SNP) | VAF 110/127 reads (87%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.953); catalogued as rs918551619, COSV100956683; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CADPS | c.3283C>T p.R1095W | Missense Mutation (SNP) | VAF 72/173 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV51869514; called by muse, mutect2, varscan2
- CEACAM1 | c.1390C>T p.R464C | Missense Mutation (SNP) | VAF 83/304 reads (27%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.759); catalogued as rs773721151, COSV50725745; called by muse, mutect2, varscan2
- COL6A3 | c.7376G>A p.R2459Q | Missense Mutation (SNP) | VAF 43/100 reads (43%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs777496872; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CSF1R | c.1400C>T p.T467M | Missense Mutation (SNP) | VAF 84/199 reads (42%) | SIFT tolerated (0.1); PolyPhen benign (0.207); catalogued as rs376388107; called by muse, mutect2, varscan2
- DNAH1 | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 144/312 reads (46%) | SIFT deleterious (0); PolyPhen possibly damaging (0.582); catalogued as rs1348264709; called by muse, mutect2, varscan2
- EXTL3 | c.1442C>T p.A481V | Missense Mutation (SNP) | VAF 197/435 reads (45%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.849); catalogued as rs764122764; called by muse, mutect2, varscan2
- GFI1B | c.691C>T p.R231C | Missense Mutation (SNP) | VAF 172/390 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs201349915, COSV59744336; called by muse, mutect2, varscan2
- GRIN1 | c.650G>A p.R217Q | Missense Mutation (SNP) | VAF 146/573 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.721); catalogued as rs201764643; called by muse, mutect2, varscan2
- KCNQ5 | c.533G>A p.R178Q | Missense Mutation (SNP) | VAF 89/220 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59655156, COSV59671441; called by muse, mutect2, varscan2
- KSR2 | c.1462C>T p.R488C | Missense Mutation (SNP) | VAF 123/343 reads (36%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.454); catalogued as rs1377362128; called by muse, mutect2, varscan2
- MYH4 | c.5039G>A p.R1680H | Missense Mutation (SNP) | VAF 133/354 reads (38%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as rs781229189, COSV55116560; called by muse, mutect2, varscan2
- MYO7B | c.4860G>A p.R1620= | Splice Region (SNP) | VAF 36/84 reads (43%) | catalogued as rs370050348, COSV101268377; called by muse, mutect2, varscan2
- NEDD9 | c.176G>C p.R59P | Missense Mutation (SNP) | VAF 76/393 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101053452, COSV65159809; called by muse, mutect2, varscan2
- PTPN3 | c.634C>T p.R212W | Missense Mutation (SNP) | VAF 64/200 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs529250315, COSV52701932; called by muse, mutect2, varscan2
- RTKN | c.311G>A p.R104Q (on ENST00000272430 / NM_001015055.2; = p.R91Q on NM_033046.2) | Missense Mutation (SNP) | VAF 35/199 reads (18%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.977); catalogued as rs758078564, COSV51961356; called by muse, mutect2, varscan2
- SLC11A2 | c.656T>C p.I219T (on ENST00000394904 / NM_001379455.1; = p.I190T on NM_000617.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 180/337 reads (53%) | SIFT deleterious (0); PolyPhen possibly damaging (0.786); catalogued as COSV100015195; called by muse, mutect2, varscan2
- SPDYC | c.868C>T p.R290C | Missense Mutation (SNP) | VAF 31/86 reads (36%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0); catalogued as rs552653826, COSV65865069; called by muse, mutect2, varscan2
- STYXL2 | c.3127C>T p.R1043C | Missense Mutation (SNP) | VAF 146/350 reads (42%) | SIFT tolerated (0.14); PolyPhen benign (0.005); catalogued as rs371920799, COSV54803001, COSV99609645; called by muse, mutect2, varscan2
- VWF | c.4609G>A p.V1537I | Missense Mutation (SNP) | VAF 43/528 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs772887330, COSV54613028; called by muse, mutect2
- ANO8 | c.1621G>A p.G541R | Missense Mutation (SNP) | VAF 31/79 reads (39%) | SIFT tolerated (0.28); PolyPhen benign (0.415); called by muse, mutect2, varscan2
- CASZ1 | c.1976G>A p.C659Y | Missense Mutation (SNP) | VAF 15/498 reads (3%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2
- CEP89 | c.555T>A p.F185L | Missense Mutation (SNP) | VAF 31/130 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.024); called by muse, mutect2, varscan2
- FMO3 | c.845C>A p.P282H | Missense Mutation (SNP) | VAF 13/27 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); called by muse, mutect2, varscan2
- HYDIN | c.4934T>C p.V1645A | Missense Mutation (SNP) | VAF 21/62 reads (34%) | SIFT deleterious (0); PolyPhen possibly damaging (0.754); called by muse, mutect2, varscan2
- STXBP5L | c.2868del p.K956Nfs*49 | Frame Shift Del (DEL) | VAF 77/191 reads (40%) | called by mutect2, pindel, varscan2
- ZNF608 | c.2619G>C p.E873D | Missense Mutation (SNP) | VAF 55/118 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.974); called by muse, mutect2, varscan2
- CHRNA7 | c.387C>T p.N129= | Silent (SNP) | VAF 3/8 reads (38%) | called by mutect2, varscan2
- DCAF12L1 | c.1131C>A p.V377= | Silent (SNP) | VAF 82/89 reads (92%) | called by muse, mutect2, varscan2
- DNAH8 | c.9309C>T p.D3103= | Silent (SNP) | VAF 22/41 reads (54%) | catalogued as rs141240104, COSV100545987; called by muse, mutect2, varscan2
- FAM47B | c.873C>T p.R291= | Silent (SNP) | VAF 177/196 reads (90%) | catalogued as rs1294363472, COSV61454803; called by muse, mutect2, varscan2
- GPR4 | c.468C>T p.D156= | Silent (SNP) | VAF 42/163 reads (26%) | catalogued as rs771369207, COSV59917682; called by muse, mutect2, varscan2
- HIVEP2 | c.4551G>A p.S1517= | Silent (SNP) | VAF 121/340 reads (36%) | catalogued as rs886762722, COSV99176378; called by muse, mutect2, varscan2
- OR10A2 | c.399T>A p.A133= | Silent (SNP) | VAF 117/291 reads (40%) | called by muse, mutect2, varscan2
- PPP1R2B | c.18C>T p.A6= | Silent (SNP) | VAF 148/294 reads (50%) | called by muse, mutect2, varscan2
- TAFA5 | c.207G>A p.A69= (on ENST00000402357 / NM_001082967.3; = p.A62= on NM_015381.7) | Silent (SNP) | VAF 167/359 reads (47%) | catalogued as rs777036601, COSV100385567; called by muse, mutect2, varscan2
- TMEM132C | c.1866C>T p.H622= | Silent (SNP) | VAF 143/307 reads (47%) | catalogued as rs190794438; called by muse, mutect2, varscan2
- TMEM200C | c.738G>A p.P246= | Silent (SNP) | VAF 19/247 reads (8%) | catalogued as rs1220600215; called by muse, mutect2
- TPSAB1 | c.93C>T p.I31= | Silent (SNP) | VAF 40/120 reads (33%) | catalogued as rs1800987; called by muse, varscan2
- VIPR2 | c.1095G>A p.S365= | Silent (SNP) | VAF 116/336 reads (35%) | catalogued as COSV51103387; called by muse, mutect2, varscan2
- KRT17P2 | n.417C>T | RNA (SNP) | VAF 95/384 reads (25%) | catalogued as rs893081388; called by muse, mutect2, varscan2
- TRIM74 | chr7:72970001 G>A | 5'Flank (SNP) | VAF 116/671 reads (17%) | catalogued as rs782598475; called by muse, mutect2, varscan2
